Somatic mutation profile of tumor specimen C3L-04739-04 (aliquot CPT0304820006) from CPTAC case C3L-04739, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.3 years (25,689 days).
Specimen C3L-04739-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b79eda0-e7b1-49ac-9d88-19a973b1ffd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04739-31 (Blood Derived Normal), aliquot CPT0304950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bb71af5-6e20-4019-95ab-a7f216e7ef28

The open-access MAF lists 464 somatic variants for this specimen: 296 protein-altering or splice-affecting, 149 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 279, Silent 149, Nonsense Mutation 11, Intron 9, RNA 3, 3'UTR 3, Splice Region 3, 3'Flank 2, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.245C>A p.T82K | Missense Mutation (SNP) | VAF 135/446 reads (30%) | SIFT deleterious, low confidence (0); catalogued as rs746496175; called by muse, mutect2, varscan2
- ACACB | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 164/481 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV58146192; called by muse, mutect2, varscan2
- ACCSL | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs759197314, COSV66580697; called by muse, mutect2, varscan2
- ADAMTS20 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV67132452, COSV67137047; called by muse, mutect2, varscan2
- ADGRG4 | c.8582C>T p.P2861L | Missense Mutation (SNP) | VAF 97/372 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769358480; called by muse, mutect2, varscan2
- ADGRV1 | c.15698T>G p.M5233R | Missense Mutation (SNP) | VAF 137/477 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV101316710; called by muse, mutect2, varscan2
- ALMS1 | c.5075C>T p.P1692L | Missense Mutation (SNP) | VAF 164/483 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1044261801; called by muse, mutect2, varscan2
- ALPK2 | c.5093C>T p.S1698L | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs375605840, COSV64490108; called by muse, mutect2, varscan2
- AQP10 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 128/380 reads (34%) | catalogued as rs753574097, COSV100270290; called by muse, mutect2, varscan2
- ARFGEF2 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 196/445 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs775999493; called by muse, mutect2, varscan2
- ARGFX | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 112/374 reads (30%) | catalogued as COSV57684068; called by muse, mutect2, varscan2
- BAHCC1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 204/525 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as COSV57034422; called by muse, mutect2, varscan2
- BRCC3 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 92/304 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1557295328; called by muse, mutect2, varscan2
- BTN1A1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 151/419 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.035); catalogued as rs752873211; called by muse, mutect2, varscan2
- C12orf56 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 96/343 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs764750881, COSV61487157; called by muse, mutect2, varscan2
- C19orf57 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 118/360 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs375174278; called by muse, mutect2, varscan2
- C1orf141 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.344); catalogued as COSV63993407; called by muse, mutect2, varscan2
- C2CD5 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 107/341 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs765582861; called by muse, mutect2, varscan2
- CBLN3 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 191/600 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1338414576; called by muse, mutect2, varscan2
- CCDC178 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.187); catalogued as COSV55761695; called by muse, mutect2, varscan2
- CDH9 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 156/372 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as rs867901234, COSV50264302, COSV50324297; called by muse, mutect2
- CEP89 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 95/317 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59862041; called by muse, mutect2, varscan2
- CEP97 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 134/357 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779653506; called by muse, mutect2, varscan2
- CFAP47 | c.2684G>A p.G895E | Missense Mutation (SNP) | VAF 195/418 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV52881559; called by muse, mutect2, varscan2
- CFHR1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 89/309 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV57625854; called by muse, mutect2, varscan2
- CHAF1B | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 139/428 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as rs751430549; called by muse, mutect2, varscan2
- CHST7 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 224/704 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs766923926, COSV52099992, COSV52101315; called by muse, varscan2
- CLCN1 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 240/503 reads (48%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs1051714088, COSV58372764; called by muse, mutect2, varscan2
- CLEC17A | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 112/372 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs763362627; called by muse, mutect2, varscan2
- COL11A1 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.489); catalogued as rs1278300568; called by muse, mutect2, varscan2
- COL18A1 | c.2729C>T p.P910L (on ENST00000359759 / NM_130444.3; = p.P675L on NM_030582.4) | Missense Mutation (SNP) | VAF 153/471 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs751547351, COSV62707144; called by muse, mutect2, varscan2
- COL4A5 | c.3527G>A p.G1176E | Missense Mutation (SNP) | VAF 154/486 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886042570, CD983330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A6 | c.3952C>T p.P1318S | Missense Mutation (SNP) | VAF 133/437 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.426); catalogued as rs896111053; called by muse, mutect2, varscan2
- CT47B1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 179/573 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV64890432; called by muse, mutect2, varscan2
- CXorf66 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 114/355 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); catalogued as rs200754289, COSV65169523, COSV65169966; called by muse, mutect2, varscan2
- CYP27C1 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1049583990; called by muse, mutect2, varscan2
- DNAH9 | c.12496G>A p.D4166N | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.273); catalogued as rs148626653; called by muse, mutect2, varscan2
- DNMBP | c.3608C>T p.P1203L | Missense Mutation (SNP) | VAF 97/277 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1257180378; called by muse, mutect2, varscan2
- EPB41L1 | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 144/587 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); catalogued as rs377204947; called by muse, varscan2
- ERICH2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 107/224 reads (48%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.38); catalogued as rs1338531926; called by muse, mutect2, varscan2
- EYA1 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58157634; called by muse, mutect2, varscan2
- F5 | c.2600G>A p.G867E | Missense Mutation (SNP) | VAF 160/453 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63123025; called by muse, mutect2, varscan2
- FGA | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 122/384 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV57395328; called by muse, mutect2, varscan2
- FGGY | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 154/359 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773164035, COSV58028023; called by muse, mutect2, varscan2
- FLG2 | c.4391G>C p.R1464T | Missense Mutation (SNP) | VAF 163/475 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV66168297; called by muse, mutect2, varscan2
- FLT3 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.393); catalogued as rs1418329483, COSV99606945; called by muse, mutect2, varscan2
- FMN2 | c.3574G>A p.G1192R | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.924); catalogued as rs1462555296; called by muse, mutect2, varscan2
- FMN2 | c.3575G>A p.G1192E | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.89); catalogued as rs1201710830, COSV60414882; called by muse, mutect2, varscan2
- GABRG2 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs146470870, COSV62715967; called by muse, mutect2, varscan2
- GALNTL5 | c.660G>A p.G220= | Splice Region (SNP) | VAF 69/297 reads (23%) | catalogued as COSV101217671, COSV101217765; called by muse, mutect2, varscan2
- GGCX | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV104374466; called by muse, mutect2, varscan2
- GIMAP8 | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 128/582 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV56231987; called by muse, mutect2, varscan2
- GPR37L1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 118/376 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs764750408; called by muse, mutect2, varscan2
- HCN1 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 137/402 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs759733460, COSV100302693, COSV57525389; called by muse, mutect2, varscan2
- HCRTR2 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 130/394 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs201301558, COSV63793801, COSV63798056, COSV63799846; called by muse, mutect2, varscan2
- IDH3B | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 133/449 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs1294818224, COSV66483139; called by muse, mutect2, varscan2
- IFFO2 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 221/465 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1417029658; called by muse, mutect2, varscan2
- IFI30 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 131/390 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs775483671, COSV69576571; called by muse, mutect2, varscan2
- KAT7 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 151/420 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV52012929; called by muse, mutect2, varscan2
- KIAA0232 | c.2609C>T p.T870I | Missense Mutation (SNP) | VAF 112/424 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs754204775; called by muse, mutect2, varscan2
- KIAA1217 | c.2503G>A p.A835T | Missense Mutation (SNP) | VAF 129/399 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs141384251; called by muse, mutect2, varscan2
- KLHL1 | c.1994G>T p.R665L | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV64774431; called by muse, mutect2
- KMT2D | c.5071C>T p.P1691S | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56491804; called by muse, mutect2, varscan2
- KPNA2 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 125/342 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV57858934; called by muse, mutect2, varscan2
- LRRC14B | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 231/563 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs574254936; called by muse, mutect2, varscan2
- LRRC30 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 110/372 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs867952372, COSV67301986, COSV67302511; called by muse, mutect2, varscan2
- LRRC7 | c.2689C>T p.P897S (on ENST00000651989 / NM_001370785.2; = p.P864S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 145/585 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50481074; called by muse, mutect2, varscan2
- MAGEC3 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 123/392 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs866786468, COSV53576159; called by muse, mutect2, varscan2
- MCM9 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 146/312 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60324310, COSV60327211; called by muse, mutect2, varscan2
- MEFV | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 191/571 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as rs545517350, CM097629, CM123814, COSV54819659, COSV54821410; called by muse, mutect2, varscan2
- MGST1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 94/350 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV50566970; called by muse, mutect2, varscan2
- MKRN3 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 170/569 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs781005844, COSV58808823; called by muse, mutect2, varscan2
- MYL10 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs758861574; called by muse, mutect2
- NFE2L3 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 196/584 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1386817188; called by muse, mutect2, varscan2
- NLGN4X | c.1476G>T p.E492D | Missense Mutation (SNP) | VAF 169/558 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52038942; called by muse, mutect2, varscan2
- NMUR2 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 117/358 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as COSV54917958; called by muse, mutect2, varscan2
- NRIP1 | c.3224G>A p.G1075E | Missense Mutation (SNP) | VAF 87/316 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749264276; called by mutect2, varscan2
- NRIP1 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 138/413 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777534057, COSV59659644; called by muse, mutect2, varscan2
- NUTM2D | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as rs1467407009; called by mutect2, varscan2
- OR10A5 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 127/338 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs867881604; called by muse, mutect2, varscan2
- OR11H4 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.129); catalogued as rs200685446, COSV59560667; called by muse, varscan2
- OR1D2 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 73/431 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160615632, COSV58921224; called by muse, mutect2, varscan2
- OR4A15 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 139/313 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.223); catalogued as rs753415282, COSV100124011, COSV59033532; called by muse, mutect2, varscan2
- OR51I1 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 129/399 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867898037, COSV66508205; called by muse, mutect2, varscan2
- OR5AK2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 110/227 reads (48%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58803707; called by muse, mutect2, varscan2
- OR6V1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 389/774 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs867782093, COSV69237344; called by muse, mutect2, varscan2
- OR8D1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs1396328612, COSV100766542; called by muse, mutect2, varscan2
- PAM | c.2291C>T p.S764F | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1385984412, COSV57211717; called by muse, mutect2, varscan2
- PCDHA12 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 181/553 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.284); catalogued as rs543806401, COSV56503478; called by muse, mutect2, varscan2
- PCDHAC1 | c.1790C>T p.S597F | Missense Mutation (SNP) | VAF 126/433 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.133); catalogued as rs782513735, COSV53845846; called by muse, mutect2, varscan2
- PCDHAC2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 142/445 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53872585; called by muse, mutect2, varscan2
- PDE1C | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 72/236 reads (31%) | catalogued as rs754659378, COSV58525641, COSV58527623; called by muse, mutect2, varscan2
- PIK3R5 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 130/317 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.103); catalogued as rs201753345; called by muse, mutect2, varscan2
- PKHD1L1 | c.12679G>A p.E4227K | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV101006627; called by muse, mutect2, varscan2
- PLCG2 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 113/419 reads (27%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.996); catalogued as rs867345397, COSV63872757; called by muse, mutect2, varscan2
- PLEKHH2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.038); catalogued as rs775181688, COSV56752270, COSV56761117; called by muse, mutect2, varscan2
- PLPPR3 | c.1516G>A p.G506S (on ENST00000520876 / NM_001270366.2; = p.G534S on NM_024888.2) | Missense Mutation (SNP) | VAF 150/532 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs763941209; called by muse, varscan2
- PPP1R3A | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 84/412 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as COSV52882748; called by muse, mutect2, varscan2
- PPP1R3A | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs868591967, COSV52876769; called by muse, mutect2, varscan2
- PPP1R9A | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 136/402 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs372926792; called by muse, mutect2, varscan2
- PPP4R3C | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 116/396 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as COSV69081150; called by muse, mutect2, varscan2
- PRG3 | c.274T>C p.C92R | Missense Mutation (SNP) | VAF 142/362 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565079470; called by muse, mutect2, varscan2
- PRKDC | c.7675A>G p.T2559A | Missense Mutation (SNP) | VAF 148/442 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs764467296; called by muse, mutect2, varscan2
- PTPN13 | c.2341C>T p.H781Y | Missense Mutation (SNP) | VAF 108/397 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1161759884; called by muse, mutect2, varscan2
- R3HDM1 | c.2003A>G p.N668S | Missense Mutation (SNP) | VAF 122/379 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs547366869, COSV51523299; called by muse, mutect2, varscan2
- RERE | c.2386C>T p.P796S | Missense Mutation (SNP) | VAF 275/1139 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1434580993; called by muse, mutect2
- RREB1 | c.4420C>T p.P1474S | Missense Mutation (SNP) | VAF 162/522 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as rs201769527, COSV58553402; called by muse, mutect2, varscan2
- SCAPER | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.954); catalogued as rs1456040886, COSV100238334, COSV57739293; called by muse, mutect2, varscan2
- SFXN3 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 125/459 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99827425; called by muse, mutect2, varscan2
- SLC26A5 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 77/317 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs150015080; called by muse, mutect2, varscan2
- SLC39A3 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 161/479 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54118677; called by muse, mutect2, varscan2
- SOAT2 | c.882G>A p.W294* | Nonsense Mutation (SNP) | VAF 157/461 reads (34%) | catalogued as COSV56858940; called by muse, mutect2, varscan2
- SPTA1 | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 104/399 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754194243, COSV63756759; called by muse, mutect2, varscan2
- SULT1A1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 161/1305 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs760293838, COSV59088402; called by muse, mutect2, varscan2
- SUOX | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 129/401 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM971432; called by muse, mutect2, varscan2
- SYNE1 | c.4070T>C p.F1357S (on ENST00000367255 / NM_182961.4; = p.F1364S on NM_033071.3) | Missense Mutation (SNP) | VAF 121/233 reads (52%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs914947519; called by muse, mutect2, varscan2
- TACC2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 153/467 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs763630843, COSV57754220; called by muse, mutect2, varscan2
- TBXA2R | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 191/631 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322165544; called by muse, mutect2, varscan2
- TCHHL1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 148/398 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs866241507, COSV64286720; called by muse, mutect2, varscan2
- TGM4 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as COSV99942202; called by muse, mutect2, varscan2
- TICAM1 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 170/501 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1211446763, COSV99941004; called by muse, mutect2, varscan2
- TLL1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50271777; called by muse, mutect2, varscan2
- TMEM132B | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 87/270 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100169782; called by muse, mutect2, varscan2
- TMEM47 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 162/464 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.272); catalogued as rs267606443, COSV52066095; called by muse, mutect2, varscan2
- TNK1 | c.1856G>A p.G619E (on ENST00000576812 / NM_001251902.2; = p.G614E on NM_003985.5) | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs1233508908; called by muse, mutect2, varscan2
- TRPV6 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 180/431 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.134); catalogued as COSV63893006; called by muse, mutect2, varscan2
- UGT2B11 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV101485306, COSV71423063; called by muse, mutect2
- UNC13C | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as rs866246818, COSV52885008; called by muse, mutect2, varscan2
- UNC80 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 157/311 reads (50%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV99781407; called by muse, mutect2, varscan2
- USP25 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99584844; called by muse, mutect2, varscan2
- VPS35L | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 93/342 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV51978409; called by muse, mutect2, varscan2
- VWA5B1 | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 133/583 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs558317313; called by muse, mutect2, varscan2
- VWF | c.6258G>A p.G2086= | Splice Region (SNP) | VAF 74/244 reads (30%) | catalogued as rs757717683; called by muse, mutect2, varscan2
- WDR87 | c.6487G>A p.E2163K | Missense Mutation (SNP) | VAF 106/345 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.421); catalogued as rs1459119161; called by muse, mutect2, varscan2
- ZFYVE28 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 113/351 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs760713826; called by muse, mutect2
- ZMIZ1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 163/520 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1205908279; called by muse, mutect2, varscan2
- ZNF226 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1051775895; called by muse, mutect2, varscan2
- ZNF334 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 152/618 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1364509012, COSV61618421; called by muse, mutect2, varscan2
- ZNF599 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 168/498 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs756885831; called by muse, mutect2, varscan2
- ZNF668 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 101/380 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV56212982; called by muse, varscan2
- ZNF668 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 159/504 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs777728754, COSV56215120; called by muse, varscan2
- ZNF723 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.164); catalogued as rs796317212; called by muse, mutect2, varscan2
- ZNF750 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 154/416 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV53958586; called by muse, mutect2, varscan2
- ZNF831 | c.3257G>A p.R1086K | Missense Mutation (SNP) | VAF 337/741 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.028); catalogued as rs933864922, COSV64039430; called by muse, mutect2, varscan2
- ABLIM1 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 76/351 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2
- AC244197.3 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 178/588 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ACLY | c.2189G>T p.G730V | Missense Mutation (SNP) | VAF 123/448 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ACLY | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 122/447 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ADAM20 | c.95G>C p.R32T | Missense Mutation (SNP) | VAF 115/376 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADGRG4 | c.8581C>T p.P2861S | Missense Mutation (SNP) | VAF 98/365 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADRA2A | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFF1 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGXT2 | c.696dup p.R233Sfs*30 | Frame Shift Ins (INS) | VAF 89/306 reads (29%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AL645922.1 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 241/726 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALKBH8 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 123/309 reads (40%) | called by muse, mutect2, varscan2
- AMOT | c.1439T>C p.V480A (on ENST00000371959 / NM_001113490.1; = p.V71A on NM_133265.3) | Missense Mutation (SNP) | VAF 20/568 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- AOC1 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 153/716 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AVEN | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTBD17 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 220/543 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTC | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- C2orf16 | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 102/370 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CAMTA1 | c.4679_4686del p.K1560Tfs*6 | Frame Shift Del (DEL) | VAF 63/373 reads (17%) | called by mutect2, pindel, varscan2
- CAPN15 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 202/648 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); called by muse, varscan2
- CAPN15 | c.3131C>T p.S1044F | Missense Mutation (SNP) | VAF 128/369 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASK | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 123/403 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CDCA7L | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 78/277 reads (28%) | called by muse, mutect2, varscan2
- CDH23 | c.5783T>G p.V1928G | Missense Mutation (SNP) | VAF 133/403 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CDH5 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 144/447 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CDK14 | c.648T>G p.D216E (on ENST00000380050 / NM_001287135.2; = p.D198E on NM_012395.3) | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CELSR1 | c.664T>A p.L222M | Missense Mutation (SNP) | VAF 164/537 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHD9 | c.4727C>T p.A1576V | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CHST7 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 232/602 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLSTN3 | c.2837G>A p.R946K | Missense Mutation (SNP) | VAF 105/329 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COL3A1 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- COMMD5 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 143/488 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- CSMD2 | c.5443C>A p.P1815T | Missense Mutation (SNP) | VAF 105/477 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD2 | c.3313A>C p.T1105P | Missense Mutation (SNP) | VAF 152/586 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTNNB1 | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 135/391 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CYP2C8 | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 108/308 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, varscan2
- CYYR1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DBH | c.1717T>C p.F573L | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- DENND2C | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 96/387 reads (25%) | called by muse, mutect2, varscan2
- DLAT | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DLGAP1 | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 110/350 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DLGAP1 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 88/321 reads (27%) | called by muse, mutect2, varscan2
- DNAH17 | c.5266A>C p.I1756L | Missense Mutation (SNP) | VAF 130/465 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- DNAH5 | c.6529G>A p.E2177K | Missense Mutation (SNP) | VAF 101/380 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- DNAH9 | c.10013C>T p.A3338V | Missense Mutation (SNP) | VAF 97/277 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- DOCK1 | c.4957C>T p.L1653F | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DPY19L1 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSCAML1 | c.5501G>A p.G1834D (on ENST00000321322; = p.G1774D on NM_020693.4) | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF4G1 | c.1865T>A p.F622Y (on ENST00000346169 / NM_198241.3; = p.F426Y on NM_004953.5) | Missense Mutation (SNP) | VAF 138/441 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- F10 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 159/430 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FANCB | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- FBXO46 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 23/582 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- FLT4 | c.3089C>T p.S1030F | Missense Mutation (SNP) | VAF 102/297 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRG2C | c.590A>C p.Q197P | Missense Mutation (SNP) | VAF 197/1041 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GABRA6 | c.1286T>A p.F429Y | Missense Mutation (SNP) | VAF 78/485 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR173 | c.140T>A p.V47E | Missense Mutation (SNP) | VAF 189/575 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GRIA4 | c.1158G>A p.K386= | Splice Region (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- GRM2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 177/540 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GTF2IRD2B | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GUCY2D | c.3077G>A p.G1026E | Missense Mutation (SNP) | VAF 70/377 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HDHD3 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 180/385 reads (47%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- HS3ST4 | c.836A>G p.K279R | Missense Mutation (SNP) | VAF 160/453 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ISYNA1 | c.823T>G p.F275V | Missense Mutation (SNP) | VAF 142/430 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ITGA2B | c.1065A>T p.E355D | Missense Mutation (SNP) | VAF 162/520 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGB6 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ6 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 125/420 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM4E | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 164/359 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- LYST | c.4615A>C p.I1539L | Missense Mutation (SNP) | VAF 146/421 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK6 | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MBOAT4 | c.556T>A p.F186I | Missense Mutation (SNP) | VAF 145/448 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MGA | c.5984A>G p.Q1995R (on ENST00000219905 / NM_001164273.1; = p.Q1786R on NM_001080541.2) | Missense Mutation (SNP) | VAF 118/400 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MGAM2 | c.6211G>A p.D2071N | Missense Mutation (SNP) | VAF 224/454 reads (49%) | SIFT tolerated, low confidence (0.37); called by muse, varscan2
- MUC22 | c.3965G>A p.G1322D | Missense Mutation (SNP) | VAF 145/502 reads (29%) | SIFT tolerated (0.33); called by muse, varscan2
- MXRA5 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 136/469 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- MYO1H | c.1598-1G>A p.X533_splice | Splice Site (SNP) | VAF 65/217 reads (30%) | called by muse, mutect2, varscan2
- MYO9B | c.6448C>T p.P2150S | Missense Mutation (SNP) | VAF 143/426 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NAP1L2 | c.602A>T p.D201V | Missense Mutation (SNP) | VAF 146/467 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.135); called by muse, varscan2
- NBEAL2 | c.1702A>T p.M568L | Missense Mutation (SNP) | VAF 169/543 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NCOR2 | c.2506C>T p.P836S | Missense Mutation (SNP) | VAF 210/601 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFATC2IP | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 173/484 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NFE2L3 | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 197/584 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- NFKBIE | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 172/529 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKAIN1 | c.223T>G p.W75G | Missense Mutation (SNP) | VAF 253/486 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NKAIN3 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKX1-1 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 141/475 reads (30%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- NLGN2 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 87/213 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPW | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 128/468 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); called by muse, varscan2
- NPW | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 132/468 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.361); called by muse, varscan2
- NRIP1 | c.3223G>A p.G1075R | Missense Mutation (SNP) | VAF 96/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NUMA1 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 180/422 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- OR4A8 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- OR52D1 | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 126/406 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5AC2 | c.384A>G p.I128M | Missense Mutation (SNP) | VAF 140/453 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR5M11 | c.145A>T p.M49L | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8H3 | c.527A>C p.H176P | Missense Mutation (SNP) | VAF 96/241 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- OTOF | c.772A>T p.I258F | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- OTX1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 198/541 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- PAPPA2 | c.4276G>A p.G1426R | Missense Mutation (SNP) | VAF 105/328 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHA13 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 101/336 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- PCDHA5 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 134/394 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PCDHB5 | c.2383A>T p.N795Y | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PCDHGB2 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 133/453 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCNX4 | c.1259C>T p.P420L (on ENST00000406854 / NM_001330177.2; = p.P186L on NM_022495.5) | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PDE4DIP | c.1888C>T p.L630F | Missense Mutation (SNP) | VAF 116/405 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDP2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 148/431 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PDZRN3 | c.2160G>A p.M720I | Missense Mutation (SNP) | VAF 137/432 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- POTEG | c.461G>A p.R154K | Missense Mutation (SNP) | VAF 84/969 reads (9%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.996); called by muse, mutect2
- PTPN21 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RBP5 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 89/293 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- RELCH | c.1465T>C p.F489L | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFPL4AL1 | c.221T>C p.I74T | Missense Mutation (SNP) | VAF 92/569 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, varscan2
- RNF222 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SACS | c.7262T>G p.F2421C | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SDK2 | c.5681T>A p.V1894E | Missense Mutation (SNP) | VAF 165/572 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SERPINB3 | c.248A>C p.H83P | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); called by muse, varscan2
- SHANK1 | c.5354C>T p.P1785L | Missense Mutation (SNP) | VAF 197/681 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- SIGLEC10 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 24/705 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); called by muse, mutect2
- SLC2A5 | c.1159C>A p.H387N | Missense Mutation (SNP) | VAF 91/441 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SLC2A5 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 94/435 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC35F4 | c.1423G>A p.E475K (on ENST00000339762 / NM_001352015.2; = p.E439K on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/383 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SLCO1B3 | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLITRK3 | c.208A>T p.S70C | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SNX19 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 133/358 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SRP54 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STAC | c.379A>G p.M127V | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- STAT5B | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 113/304 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- STYXL2 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 181/545 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SUGP1 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 112/380 reads (29%) | called by muse, mutect2, varscan2
- SULT1E1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- SYNE1 | c.745G>A p.E249K (on ENST00000367255 / NM_182961.4; = p.E256K on NM_033071.3) | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- SYT1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 113/343 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYT1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 106/313 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by mutect2, varscan2
- TAS2R16 | c.64A>T p.I22F | Missense Mutation (SNP) | VAF 108/524 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TBC1D8 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 154/424 reads (36%) | called by muse, mutect2, varscan2
- TBXA2R | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 192/632 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THSD7B | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 96/341 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR7 | c.2495C>T p.T832I | Missense Mutation (SNP) | VAF 130/470 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- TRIM24 | c.1906G>A p.D636N (on ENST00000343526 / NM_015905.3; = p.D602N on NM_003852.4) | Missense Mutation (SNP) | VAF 228/423 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TRIM42 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 166/455 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- TRIOBP | c.3471C>A p.C1157* | Nonsense Mutation (SNP) | VAF 173/516 reads (34%) | called by muse, mutect2, varscan2
- TRPV6 | c.147A>T p.K49N | Missense Mutation (SNP) | VAF 185/433 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- TUBGCP5 | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXNDC16 | c.34A>G p.I12V | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2B10 | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- VWA2 | c.2225G>T p.W742L | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- VWA5B2 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 113/367 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- VWA5B2 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 118/375 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ZBTB9 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 176/554 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF202 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2
- ZNF202 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 44/393 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2
- ZNF439 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 123/403 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ACTN3 | c.1071C>A p.T357= | Silent (SNP) | VAF 41/277 reads (15%) | called by muse, mutect2, varscan2
- ADAM22 | c.2430T>G p.S810= | Silent (SNP) | VAF 90/308 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.1380G>A p.G460= | Silent (SNP) | VAF 83/233 reads (36%) | called by muse, mutect2, varscan2
- ADH1B | c.675C>T p.I225= | Silent (SNP) | VAF 125/523 reads (24%) | called by muse, mutect2, varscan2
- AMIGO2 | c.285G>A p.L95= | Silent (SNP) | VAF 135/450 reads (30%) | catalogued as rs751388566; called by muse, mutect2, varscan2
- ANKRD30A | c.3456G>A p.L1152= (on ENST00000611781; = p.L1096= on NM_052997.2) | Silent (SNP) | VAF 78/240 reads (33%) | called by muse, mutect2, varscan2
- ARAF | c.1044C>T p.A348= | Silent (SNP) | VAF 138/450 reads (31%) | called by muse, mutect2, varscan2
- ARMC6 | c.252C>T p.S84= (on ENST00000392336; = p.S59= on NM_033415.4) | Silent (SNP) | VAF 131/356 reads (37%) | called by muse, mutect2, varscan2
- ATP2C2 | c.153C>T p.A51= | Silent (SNP) | VAF 93/356 reads (26%) | catalogued as rs781575842; called by muse, mutect2, varscan2
- ATP7A | c.2541C>T p.I847= | Silent (SNP) | VAF 77/289 reads (27%) | catalogued as rs1569549986, COSV58448386; called by muse, mutect2, varscan2
- BICRA | c.3088C>T p.L1030= | Silent (SNP) | VAF 57/202 reads (28%) | called by muse, mutect2, varscan2
- BSN | c.3357C>T p.H1119= | Silent (SNP) | VAF 162/469 reads (35%) | catalogued as rs1302174495; called by muse, mutect2, varscan2
- C6orf132 | c.1338C>T p.N446= | Silent (SNP) | VAF 151/425 reads (36%) | catalogued as COSV100541138; called by muse, mutect2, varscan2
- CABP2 | c.504G>A p.G168= | Silent (SNP) | VAF 54/380 reads (14%) | catalogued as rs1017085785, COSV99590836; called by muse, mutect2, varscan2
- CACNA1D | c.4008C>T p.I1336= (on ENST00000350061 / NM_001128840.3; = p.I1356= on NM_000720.4) | Silent (SNP) | VAF 72/292 reads (25%) | called by muse, mutect2, varscan2
- CADM4 | c.249C>T p.S83= | Silent (SNP) | VAF 169/440 reads (38%) | called by muse, mutect2, varscan2
- CCL4L2 | c.120G>A p.A40= | Silent (SNP) | VAF 138/747 reads (18%) | catalogued as rs1300326228; called by muse, mutect2, varscan2
- CDH20 | c.2352C>T p.F784= | Silent (SNP) | VAF 77/429 reads (18%) | catalogued as COSV53015980; called by muse, mutect2, varscan2
- CDK13 | c.4485G>A p.R1495= | Silent (SNP) | VAF 105/332 reads (32%) | catalogued as COSV51706281; called by muse, varscan2
- CFAP47 | c.2685G>A p.G895= | Silent (SNP) | VAF 192/413 reads (46%) | catalogued as COSV52882001; called by muse, mutect2, varscan2
- CLIP3 | c.1086G>A p.K362= | Silent (SNP) | VAF 150/456 reads (33%) | catalogued as COSV53325195; called by muse, mutect2, varscan2
- CNGA2 | c.1572C>T p.I524= | Silent (SNP) | VAF 184/524 reads (35%) | called by muse, mutect2, varscan2
- CNOT1 | c.1509C>T p.I503= | Silent (SNP) | VAF 142/405 reads (35%) | called by muse, mutect2, varscan2
- CRYGB | c.300G>A p.R100= | Silent (SNP) | VAF 127/242 reads (52%) | called by muse, mutect2
- CSF2RB | c.1804C>T p.L602= | Silent (SNP) | VAF 184/602 reads (31%) | called by muse, mutect2, varscan2
- CUL4B | c.1494C>T p.I498= | Silent (SNP) | VAF 81/315 reads (26%) | called by muse, mutect2, varscan2
- CYP2C8 | c.657C>T p.F219= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as COSV100988032; called by muse, varscan2
- CYP4F11 | c.360G>A p.K120= | Silent (SNP) | VAF 137/435 reads (31%) | catalogued as COSV104372526, COSV99930980; called by muse, mutect2, varscan2
- DEFB116 | c.96G>A p.K32= | Silent (SNP) | VAF 154/301 reads (51%) | catalogued as COSV68722309; called by muse, mutect2, varscan2
- DEFB121 | c.9C>T p.L3= | Silent (SNP) | VAF 216/474 reads (46%) | catalogued as COSV66236106; called by muse, mutect2, varscan2
- DLGAP1 | c.1998G>A p.G666= | Silent (SNP) | VAF 110/352 reads (31%) | catalogued as rs1168791736; called by muse, mutect2, varscan2
- DNA2 | c.243C>T p.I81= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV64429886; called by muse, mutect2, varscan2
- DNAH10 | c.13494G>A p.R4498= (on ENST00000409039; = p.R4437= on NM_207437.3) | Silent (SNP) | VAF 130/489 reads (27%) | catalogued as rs374033130; called by muse, mutect2, varscan2
- DNAH8 | c.1278C>T p.F426= | Silent (SNP) | VAF 61/216 reads (28%) | called by muse, mutect2, varscan2
- DSC3 | c.2364C>T p.T788= | Silent (SNP) | VAF 73/434 reads (17%) | catalogued as rs990454578, COSV64575492; called by muse, mutect2, varscan2
- DTX1 | c.654C>T p.I218= | Silent (SNP) | VAF 122/401 reads (30%) | catalogued as COSV57497317; called by muse, mutect2, varscan2
- DYSF | c.1206G>A p.V402= | Silent (SNP) | VAF 98/354 reads (28%) | called by muse, mutect2, varscan2
- ENPP3 | c.1368C>T p.I456= | Silent (SNP) | VAF 129/257 reads (50%) | catalogued as rs186734779, COSV62954216; called by muse, mutect2, varscan2
- F8 | c.4440C>T p.S1480= | Silent (SNP) | VAF 169/489 reads (35%) | catalogued as COSV64272311; called by muse, mutect2, varscan2
- FANCD2OS | c.243G>A p.T81= | Silent (SNP) | VAF 154/464 reads (33%) | catalogued as rs143493769; called by muse, mutect2, varscan2
- FGF23 | c.654G>A p.P218= | Silent (SNP) | VAF 209/549 reads (38%) | catalogued as rs369035509; called by muse, mutect2, varscan2
- FLRT2 | c.132G>A p.R44= | Silent (SNP) | VAF 156/469 reads (33%) | catalogued as rs1166701000, COSV58145802; called by muse, mutect2, varscan2
- FMR1 | c.1782A>G p.T594= | Silent (SNP) | VAF 131/432 reads (30%) | catalogued as COSV54427710; called by muse, mutect2, varscan2
- FOXA3 | c.193C>T p.L65= | Silent (SNP) | VAF 215/692 reads (31%) | called by muse, mutect2, varscan2
- FYB2 | c.792C>T p.P264= | Silent (SNP) | VAF 272/534 reads (51%) | called by muse, mutect2, varscan2
- GAREM2 | c.1878G>A p.P626= | Silent (SNP) | VAF 125/503 reads (25%) | catalogued as rs372621978, COSV101024313; called by muse, mutect2, varscan2
- GDF10 | c.687G>A p.E229= | Silent (SNP) | VAF 165/578 reads (29%) | catalogued as rs1555207540; called by muse, mutect2, varscan2
- GDF5 | c.954G>A p.R318= | Silent (SNP) | VAF 155/729 reads (21%) | catalogued as COSV100976683, COSV65499510, COSV65501031; called by muse, mutect2, varscan2
- GLUD2 | c.135C>T p.L45= | Silent (SNP) | VAF 197/657 reads (30%) | catalogued as rs781004785; called by muse, mutect2
- GLUL | c.810C>T p.I270= | Silent (SNP) | VAF 64/225 reads (28%) | catalogued as rs753853643, COSV59383121; called by muse, mutect2, varscan2
- GPR39 | c.945G>A p.T315= | Silent (SNP) | VAF 145/448 reads (32%) | catalogued as rs766108578; called by muse, mutect2, varscan2
- GTF3C1 | c.1431G>A p.E477= | Silent (SNP) | VAF 126/353 reads (36%) | called by muse, mutect2, varscan2
- HPN | c.858G>T p.V286= | Silent (SNP) | VAF 182/522 reads (35%) | called by muse, mutect2
- HS3ST4 | c.1182C>T p.F394= | Silent (SNP) | VAF 105/376 reads (28%) | catalogued as COSV58803974; called by muse, mutect2, varscan2
- IGKV1D-16 | c.27C>T p.L9= | Silent (SNP) | VAF 133/458 reads (29%) | catalogued as rs770188120; called by muse, mutect2, varscan2
- IGLV3-27 | c.255A>T p.S85= | Silent (SNP) | VAF 70/275 reads (25%) | called by muse, mutect2, varscan2
- IGSF22 | c.690G>A p.E230= | Silent (SNP) | VAF 92/311 reads (30%) | called by muse, mutect2, varscan2
- INAVA | c.975G>A p.K325= | Silent (SNP) | VAF 139/467 reads (30%) | called by muse, mutect2, varscan2
- ITGA4 | c.1128C>T p.G376= | Silent (SNP) | VAF 87/217 reads (40%) | catalogued as rs199782465, COSV99276856; called by muse, mutect2, varscan2
- KCNG1 | c.415C>T p.L139= | Silent (SNP) | VAF 152/669 reads (23%) | called by muse, mutect2, varscan2
- LILRB1 | c.825G>A p.E275= (on ENST00000427581; = p.E239= on NM_006669.6) | Silent (SNP) | VAF 184/581 reads (32%) | called by muse, mutect2, varscan2
- LRFN1 | c.501G>C p.L167= | Silent (SNP) | VAF 137/423 reads (32%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.678C>T p.A226= (on ENST00000392000 / NM_001137552.2; = p.A202= on NM_004735.4) | Silent (SNP) | VAF 120/231 reads (52%) | catalogued as rs1384110134; called by muse, mutect2, varscan2
- LRWD1 | c.126C>T p.L42= | Silent (SNP) | VAF 139/399 reads (35%) | catalogued as rs550399566; called by muse, mutect2, varscan2
- LZTS1 | c.831C>T p.L277= | Silent (SNP) | VAF 141/469 reads (30%) | catalogued as COSV99742674; called by muse, mutect2, varscan2
- MALRD1 | c.405C>T p.F135= | Silent (SNP) | VAF 85/287 reads (30%) | called by muse, mutect2, varscan2
- MGAM | c.1038C>T p.L346= | Silent (SNP) | VAF 241/453 reads (53%) | catalogued as rs368638022, COSV72074535; called by muse, mutect2, varscan2
- MIIP | c.1029C>T p.S343= | Silent (SNP) | VAF 156/594 reads (26%) | catalogued as rs566927318; called by muse, mutect2, varscan2
- MOCOS | c.1503C>T p.A501= | Silent (SNP) | VAF 68/409 reads (17%) | catalogued as COSV99732708; called by muse, mutect2, varscan2
- MRGPRD | c.144G>A p.V48= | Silent (SNP) | VAF 46/354 reads (13%) | catalogued as rs771460184; called by muse, mutect2, varscan2
- MRPS28 | c.387G>T p.V129= | Silent (SNP) | VAF 54/175 reads (31%) | called by muse, mutect2, varscan2
- MUC16 | c.15291C>T p.F5097= | Silent (SNP) | VAF 118/365 reads (32%) | called by muse, mutect2, varscan2
- MYH9 | c.4020C>T p.S1340= | Silent (SNP) | VAF 142/480 reads (30%) | catalogued as COSV53388135; called by muse, mutect2, varscan2
- NACAD | c.4536G>A p.E1512= | Silent (SNP) | VAF 110/391 reads (28%) | called by muse, mutect2, varscan2
- NADSYN1 | c.1567C>T p.L523= | Silent (SNP) | VAF 88/197 reads (45%) | called by muse, mutect2, varscan2
- NGDN | c.813C>T p.S271= | Silent (SNP) | VAF 125/409 reads (31%) | called by muse, mutect2, varscan2
- NHS | c.1692C>T p.S564= | Silent (SNP) | VAF 194/574 reads (34%) | called by muse, mutect2, varscan2
- NLRP8 | c.621C>T p.A207= | Silent (SNP) | VAF 161/449 reads (36%) | called by muse, mutect2, varscan2
- NPPB | c.369C>T p.S123= | Silent (SNP) | VAF 107/455 reads (24%) | called by muse, mutect2, varscan2
- OR10H3 | c.348C>T p.L116= | Silent (SNP) | VAF 123/435 reads (28%) | called by muse, mutect2, varscan2
- OR1B1 | c.657C>T p.L219= | Silent (SNP) | VAF 124/277 reads (45%) | catalogued as rs776196268; called by muse, mutect2, varscan2
- OR1M1 | c.276C>T p.I92= | Silent (SNP) | VAF 116/411 reads (28%) | catalogued as COSV70036544; called by muse, varscan2
- OR1M1 | c.312C>T p.F104= | Silent (SNP) | VAF 122/426 reads (29%) | catalogued as COSV101447561, COSV70037154; called by muse, varscan2
- OR4C12 | c.51G>A p.Q17= | Silent (SNP) | VAF 75/285 reads (26%) | called by muse, mutect2, varscan2
- OR4C5 | c.381C>T p.F127= | Silent (SNP) | VAF 120/386 reads (31%) | catalogued as COSV60561489; called by muse, mutect2
- OR4K13 | c.255C>T p.F85= | Silent (SNP) | VAF 113/341 reads (33%) | catalogued as rs754907700, COSV59860138; called by muse, mutect2, varscan2
- OR4Q2 | c.186C>T p.F62= | Silent (SNP) | VAF 82/258 reads (32%) | called by muse, mutect2, varscan2
- OR5T3 | c.153G>A p.L51= | Silent (SNP) | VAF 47/354 reads (13%) | catalogued as COSV100282917, COSV57380033; called by muse, mutect2, varscan2
- OR8H2 | c.150C>T p.I50= | Silent (SNP) | VAF 44/330 reads (13%) | catalogued as COSV100542461; called by muse, mutect2, varscan2
- OTOG | c.3801G>A p.V1267= | Silent (SNP) | VAF 132/435 reads (30%) | catalogued as rs1338310908; called by muse, mutect2, varscan2
- PAPPA2 | c.4728G>A p.K1576= | Silent (SNP) | VAF 75/262 reads (29%) | catalogued as COSV62810988; called by muse, mutect2, varscan2
- PCDH15 | c.4539C>T p.F1513= | Silent (SNP) | VAF 94/344 reads (27%) | called by muse, mutect2, varscan2
- PCDHA9 | c.327C>T p.I109= | Silent (SNP) | VAF 225/475 reads (47%) | catalogued as rs782403566, COSV65325951; called by muse, mutect2, varscan2
- PCDHAC1 | c.939G>A p.R313= | Silent (SNP) | VAF 114/417 reads (27%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1158C>T p.I386= | Silent (SNP) | VAF 156/460 reads (34%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1542G>C p.L514= | Silent (SNP) | VAF 24/554 reads (4%) | called by muse, mutect2
- PCNX4 | c.1260C>T p.P420= (on ENST00000406854 / NM_001330177.2; = p.P186= on NM_022495.5) | Silent (SNP) | VAF 84/319 reads (26%) | called by muse, mutect2, varscan2
- PDE3B | c.222C>T p.P74= | Silent (SNP) | VAF 158/517 reads (31%) | called by muse, mutect2, varscan2
- PIEZO2 | c.5511C>T p.F1837= | Silent (SNP) | VAF 164/521 reads (31%) | catalogued as rs773508178, COSV53291634; called by muse, mutect2, varscan2
- PKN1 | c.2505C>T p.P835= | Silent (SNP) | VAF 126/415 reads (30%) | catalogued as rs760683783; called by muse, mutect2, varscan2
- PRAMEF18 | c.798G>A p.L266= | Silent (SNP) | VAF 240/1156 reads (21%) | called by muse, mutect2, varscan2
- PRR14L | c.5127C>T p.S1709= | Silent (SNP) | VAF 140/454 reads (31%) | called by muse, mutect2, varscan2
- PSMD4 | c.1074C>T p.S358= | Silent (SNP) | VAF 161/454 reads (35%) | catalogued as COSV100924674; called by muse, mutect2, varscan2
- RAB3GAP2 | c.438T>C p.S146= | Silent (SNP) | VAF 97/300 reads (32%) | called by muse, mutect2, varscan2
- RFX2 | c.336A>G p.P112= | Silent (SNP) | VAF 26/622 reads (4%) | called by muse, mutect2
- RFX7 | c.3927T>C p.F1309= (on ENST00000559447 / NM_001368074.1; = p.F1406= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 109/344 reads (32%) | called by muse, mutect2, varscan2
- RGL3 | c.1026C>T p.S342= | Silent (SNP) | VAF 124/393 reads (32%) | catalogued as COSV63387171; called by muse, mutect2, varscan2
- RREB1 | c.4419C>T p.G1473= | Silent (SNP) | VAF 162/522 reads (31%) | called by muse, mutect2, varscan2
- RXRA | c.768G>A p.L256= | Silent (SNP) | VAF 12/243 reads (5%) | called by muse, mutect2
- SAMD3 | c.771G>A p.R257= | Silent (SNP) | VAF 93/218 reads (43%) | catalogued as COSV63720777; called by muse, mutect2, varscan2
- SATB1 | c.1773G>A p.Q591= | Silent (SNP) | VAF 79/269 reads (29%) | catalogued as rs1357521627; called by muse, mutect2, varscan2
- SCN1A | c.4611C>T p.F1537= (on ENST00000303395 / NM_001202435.3; = p.F1526= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/205 reads (50%) | catalogued as rs747556687, COSV57664442, COSV57688162; called by muse, mutect2, varscan2
- SEMA5A | c.2841C>T p.I947= | Silent (SNP) | VAF 108/239 reads (45%) | catalogued as COSV66785572; called by muse, mutect2, varscan2
- SERPINA5 | c.837G>A p.E279= | Silent (SNP) | VAF 119/424 reads (28%) | catalogued as rs150243827; called by muse, mutect2, varscan2
- SFTPB | c.480G>T p.L160= | Silent (SNP) | VAF 176/583 reads (30%) | called by muse, mutect2, varscan2
- SIGIRR | c.393C>T p.A131= | Silent (SNP) | VAF 156/516 reads (30%) | catalogued as rs1240565120, COSV58989502; called by muse, mutect2, varscan2
- SIGLEC8 | c.1023G>A p.L341= | Silent (SNP) | VAF 83/324 reads (26%) | called by muse, mutect2, varscan2
- SMAD9 | c.18C>T p.P6= | Silent (SNP) | VAF 22/288 reads (8%) | catalogued as rs762959480; called by muse, mutect2
- SMG6 | c.1284G>A p.A428= | Silent (SNP) | VAF 54/371 reads (15%) | catalogued as rs763042110, COSV53966492; called by muse, mutect2, varscan2
- SNRPA1 | c.237A>C p.I79= | Silent (SNP) | VAF 96/262 reads (37%) | catalogued as COSV54258357; called by muse, mutect2, varscan2
- SORCS3 | c.2154G>A p.R718= | Silent (SNP) | VAF 96/319 reads (30%) | catalogued as rs267602359, COSV63796572; called by muse, mutect2, varscan2
- SPATA31D1 | c.2859G>A p.Q953= | Silent (SNP) | VAF 151/306 reads (49%) | called by muse, mutect2, varscan2
- SUOX | c.795C>T p.A265= | Silent (SNP) | VAF 127/400 reads (32%) | catalogued as rs201980087; called by muse, mutect2, varscan2
- TACC2 | c.540G>A p.K180= | Silent (SNP) | VAF 153/460 reads (33%) | catalogued as COSV57768631; called by muse, mutect2, varscan2
- TAF1 | c.4680T>A p.V1560= (on ENST00000373790 / NM_138923.4; = p.V1581= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/303 reads (30%) | called by muse, mutect2, varscan2
- TAF1L | c.1212T>C p.F404= | Silent (SNP) | VAF 153/349 reads (44%) | called by muse, mutect2, varscan2
- TECPR1 | c.1428C>T p.P476= | Silent (SNP) | VAF 161/479 reads (34%) | catalogued as rs376519132; called by muse, mutect2, varscan2
- TECTA | c.2823C>T p.F941= | Silent (SNP) | VAF 53/345 reads (15%) | called by muse, mutect2, varscan2
- THSD4 | c.219G>A p.V73= | Silent (SNP) | VAF 159/499 reads (32%) | called by muse, mutect2, varscan2
- THSD7A | c.4372C>T p.L1458= | Silent (SNP) | VAF 85/307 reads (28%) | called by muse, mutect2, varscan2
- TLR7 | c.1653C>T p.N551= | Silent (SNP) | VAF 158/506 reads (31%) | called by muse, mutect2, varscan2
- TNIK | c.1284G>A p.E428= | Silent (SNP) | VAF 142/462 reads (31%) | catalogued as rs951458474, COSV52692514; called by muse, mutect2, varscan2
- TONSL | c.2388C>T p.I796= | Silent (SNP) | VAF 174/534 reads (33%) | called by muse, varscan2
- TRPC3 | c.1785C>T p.F595= (on ENST00000379645 / NM_001366479.2; = p.F522= on NM_003305.2) | Silent (SNP) | VAF 68/252 reads (27%) | catalogued as COSV53376932; called by muse, mutect2, varscan2
- TSPAN16 | c.201C>T p.I67= | Silent (SNP) | VAF 147/454 reads (32%) | catalogued as rs769410846; called by muse, mutect2, varscan2
- TTC22 | c.705G>A p.R235= | Silent (SNP) | VAF 109/500 reads (22%) | catalogued as rs1475859511, COSV64881443; called by muse, mutect2, varscan2
- UPK1B | c.255G>A p.R85= | Silent (SNP) | VAF 90/284 reads (32%) | catalogued as rs868042875, COSV51767043; called by muse, mutect2, varscan2
- VGLL4 | c.279C>T p.C93= | Silent (SNP) | VAF 95/349 reads (27%) | called by muse, mutect2, varscan2
- WDR27 | c.1020T>C p.C340= | Silent (SNP) | VAF 99/197 reads (50%) | called by muse, mutect2, varscan2
- XIRP1 | c.894G>A p.E298= | Silent (SNP) | VAF 176/544 reads (32%) | catalogued as rs377117197; called by muse, mutect2, varscan2
- XIRP2 | c.3972C>T p.F1324= (on ENST00000628543; = p.F1499= on NM_152381.6) | Silent (SNP) | VAF 129/273 reads (47%) | catalogued as rs201676457; called by muse, mutect2, varscan2
- ZBED9 | c.2172G>A p.G724= | Silent (SNP) | VAF 95/320 reads (30%) | catalogued as COSV71729215; called by muse, mutect2, varscan2
- ZNF142 | c.2205C>T p.H735= (on ENST00000411696 / NM_001379660.1; = p.H535= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 140/374 reads (37%) | catalogued as rs1428199348; called by muse, mutect2, varscan2
- ZNF441 | c.1842C>T p.P614= | Silent (SNP) | VAF 145/402 reads (36%) | called by muse, mutect2, varscan2
- ZNF519 | c.1398C>A p.G466= | Silent (SNP) | VAF 116/396 reads (29%) | called by mutect2, varscan2
- ZNF668 | c.1818C>T p.P606= | Silent (SNP) | VAF 100/371 reads (27%) | catalogued as COSV56216364; called by muse, varscan2
- ZNF676 | c.645C>T p.T215= (on ENST00000650058; = p.T183= on NM_001001411.3) | Silent (SNP) | VAF 90/282 reads (32%) | catalogued as rs1177490649; called by muse, varscan2
- ZNF831 | c.1395G>A p.R465= | Silent (SNP) | VAF 43/737 reads (6%) | catalogued as rs201612727; called by muse, mutect2
- ZSCAN18 | c.588G>A p.Q196= | Silent (SNP) | VAF 117/391 reads (30%) | called by muse, mutect2, varscan2
- ADRA2B | c.*1675C>T | 3'UTR (SNP) | VAF 94/321 reads (29%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.870G>A | RNA (SNP) | VAF 89/389 reads (23%) | catalogued as rs3111685, COSV71422429; called by muse, mutect2, varscan2
- C4orf50 | chr4:5989957 C>T | 5'Flank (SNP) | VAF 84/320 reads (26%) | called by muse, mutect2, varscan2
- CD300LG | c.885+650C>T | Intron (SNP) | VAF 148/434 reads (34%) | catalogued as COSV99517166; called by muse, mutect2, varscan2
- CTDSPL2 | c.*1225T>C | 3'UTR (SNP) | VAF 93/307 reads (30%) | called by muse, mutect2, varscan2
- GNAS-AS1 | chr20:58826093 A>G | 3'Flank (SNP) | VAF 97/418 reads (23%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-28954A>G | Intron (SNP) | VAF 78/262 reads (30%) | called by muse, mutect2, varscan2
- MEFV | c.1760-76T>G | Intron (SNP) | VAF 131/415 reads (32%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671171 G>A | 3'Flank (SNP) | VAF 78/319 reads (24%) | called by muse, mutect2, varscan2
- MUCL3 | c.946+753C>T | Intron (SNP) | VAF 239/877 reads (27%) | catalogued as rs1315123669; called by muse, mutect2, varscan2
- MUCL3 | c.946+754C>T | Intron (SNP) | VAF 236/878 reads (27%) | catalogued as COSV100424056; called by muse, mutect2, varscan2
- P4HTM | c.1074-13C>T | Intron (SNP) | VAF 122/445 reads (27%) | called by muse, mutect2, varscan2
- PML | c.1710+1276C>T | Intron (SNP) | VAF 156/444 reads (35%) | catalogued as rs1451615247; called by muse, mutect2, varscan2
- REXO1L1P | n.874G>A | RNA (SNP) | VAF 14/776 reads (2%) | catalogued as rs1311628583; called by muse, mutect2
- SLC22A17 | n.997C>T | RNA (SNP) | VAF 115/363 reads (32%) | called by muse, mutect2, varscan2
- SORBS2 | c.684+7739G>A | Intron (SNP) | VAF 204/625 reads (33%) | catalogued as rs181420190; called by muse, mutect2, varscan2
- UNC13B | c.761+5277C>T | Intron (SNP) | VAF 84/168 reads (50%) | called by muse, mutect2, varscan2
- USP42 | c.-35A>G | 5'UTR (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
- ZDHHC8 | c.*1671G>A | 3'UTR (SNP) | VAF 185/590 reads (31%) | called by muse, mutect2, varscan2
